Somatic mutation profile of tumor specimen 0DXDVU from CCDI case PBCRHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 0.3 years (105 days).
Specimen 0DXDVU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1a34c8-f59d-4e86-8910-b0874f83f918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXDV3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/551ae749-06ac-48e7-8f1e-78f0b5198653

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Missense Mutation 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR146 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZNF891 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 279/906 reads (31%) | called by muse, mutect2, varscan2
- TACR1 | c.231G>A p.A77= | Silent (SNP) | VAF 26/478 reads (5%) | catalogued as COSV59479285; called by muse, mutect2
- GOLGA6L3 | n.815G>A | RNA (SNP) | VAF 6/22 reads (27%) | catalogued as rs747354643; called by muse, varscan2
